Somatic mutation profile of tumor specimen MP2PRT-PARIYN-TMP1-A (aliquot MP2PRT-PARIYN-TMP1-A-1-0-D-A82K-36) from MP2PRT case MP2PRT-PARIYN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,394 days).
Specimen MP2PRT-PARIYN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8211ff91-959d-472c-b47c-937b04082d83.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARIYN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARIYN-NB1-A-1-0-D-A82K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4a5e16f8-7534-4eb7-bdbf-6de99398a14c

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 16, Silent 6, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 36/145 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- ARHGAP31 | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 239/753 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV51795140; called by muse, mutect2, varscan2
- CACNG4 | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 194/665 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs535107281, COSV50925479; called by muse, mutect2, varscan2
- HDLBP | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 121/433 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.131); catalogued as rs777767470; called by muse, mutect2, varscan2
- KIAA0100 | c.514A>G p.R172G | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.067); catalogued as COSV101197409; called by muse, mutect2
- NOTCH3 | c.5942G>A p.R1981H | Missense Mutation (SNP) | VAF 90/782 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771678721, COSV54655951; called by muse, mutect2, varscan2
- SLITRK3 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.677); catalogued as COSV53847947; called by muse, mutect2, varscan2
- TBP | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 36/159 reads (23%) | catalogued as rs756008941; called by muse, mutect2, varscan2
- ACAN | c.5962C>A p.Q1988K | Missense Mutation (SNP) | VAF 138/448 reads (31%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARAP2 | c.2769G>T p.W923C | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP31 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 211/635 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- ARHGEF5 | c.566A>G p.H189R | Missense Mutation (SNP) | VAF 143/1291 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- JAK2 | c.975_976insTAAAT p.V326* | Nonsense Mutation (INS) | VAF 13/41 reads (32%) | called by mutect2, pindel*, varscan2*
- MGAT5B | c.1189A>G p.T397A | Missense Mutation (SNP) | VAF 211/614 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SCG2 | c.1092C>G p.D364E | Missense Mutation (SNP) | VAF 117/329 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SEMA6B | c.245G>T p.R82M | Missense Mutation (SNP) | VAF 151/430 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC80 | c.2135G>T p.S712I | Missense Mutation (SNP) | VAF 107/339 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ZSCAN12 | c.1792T>C p.S598P | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- ACAN | c.5961G>A p.L1987= | Silent (SNP) | VAF 138/449 reads (31%) | catalogued as rs1293602360; called by muse, mutect2, varscan2
- ARHGAP22 | c.1755G>A p.P585= | Silent (SNP) | VAF 272/806 reads (34%) | catalogued as rs1380771158; called by muse, mutect2, varscan2
- EPN2 | c.1284G>A p.A428= | Silent (SNP) | VAF 158/579 reads (27%) | catalogued as rs147435325; called by muse, mutect2, varscan2
- GRIN2B | c.807G>A p.V269= | Silent (SNP) | VAF 218/646 reads (34%) | catalogued as rs61754644; called by muse, mutect2, varscan2
- MMP3 | c.132C>T p.L44= | Silent (SNP) | VAF 45/152 reads (30%) | catalogued as rs782502378, COSV55405416; called by muse, mutect2, varscan2
- MX1 | c.345G>A p.V115= | Silent (SNP) | VAF 141/441 reads (32%) | called by muse, mutect2, varscan2
